TCGA case TCGA-OR-A5LM — Adrenocortical Carcinoma (TCGA-ACC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Adrenal gland; Tissue source site: University of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e612ef6e-f3f2-44be-ab15-8e4095687cd6

Demographics
Sex at birth: male; Country of residence at enrollment: France; Age at index: 23 years; Vital status: Alive.

Diagnoses (1)
1. Adrenal cortical carcinoma: ICD-O-3 morphology code: 8370/3; ICD-10 code: C74.0; Tissue or organ of origin: Cortex of adrenal gland; Site of resection or biopsy: Adrenal gland, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 23.9 years (8,735 days); Year of diagnosis: 2008; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,858 days (5.1 years); Ensat clinical m: M0; Ensat pathologic n: N0; Ensat pathologic stage: Stage II; Ensat pathologic t: T2; Weiss assessment findings: Atypical Mitotic Figures / Cytoplasm presence <= to 25% / Diffuse Architecture / Invasion of Tumor Capsule / Mitotic Rate > 5/50 HPF / Necrosis / Nuclear Grade III or IV; Weiss assessment score: 7.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 32.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Mitotane; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Therapeutic levels achieved: Yes; Therapeutic target level: >14 mg/L.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Mitotane; Therapeutic levels achieved: No; Therapeutic target level: >14 mg/L; Timepoint category: Recurrence.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Day 1,858 (within 3 months of surgery): Disease response: Tumor Free.
- Imaging type: CT Scan; Imaging findings: Normal; Timepoint: Preoperative.

Molecular and laboratory tests
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 18.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factor method of diagnosis: Both Clinical and Biochemical Assessments; Risk factors: Estrogen Excess.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-OR-A5LM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 120 mg.
  Slide TCGA-OR-A5LM-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-OR-A5LM-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-OR-A5LM-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Pharmaceutical treatment mitotane indicator: Yes; Pharmaceutical treatment mitotane theraputic levels: Yes; Pharmaceutical treatment mitotane theraputic at rec: No; Clinical status within 3 mths surgery: No imaging evidence of disease; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Adrenal; Histologic diagnosis: Adrenocortical carcinoma- Usual Type; Ct scan preop results: Yes; Lymph nodes examined: Yes; Mitoses per 50 hpf: 18.
- Primary pathology, Weiss assessment report, Weiss assessment categories: Nuclear grade III IV: Nuclear Grade III or IV Present; Mitotic rate: Mitotic Rate > 5/50 HPF Present; Atypical mitotic figures: Atypical Mitotic Figures Present; Cytoplasm presence less than equal 25 percent: Cytoplasm presence <= 25% Present; Diffuse architecture: Diffuse Architecture Present; Necrosis: Necrosis Present; Weiss venous invasion: Venous Invasion Absent; Sinusoid invasion: Sinusoid Invasion Absent; Invasion of tumor capsule: Invasion of Tumor Capsule Present.
- Primary pathology, Excess adrenal hormone history types: History adrenal hormone excess: Estrogen.
- Primary pathology, Germline genotype testing report: Molecular studies others performed: No.
- Follow-up form 1: Lost to follow-up: No; Pharmaceutical treatment mitotane theraputic levels: Yes; Clinical status within 3 mths surgery: No imaging evidence of disease; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,858 days; disease-specific survival: no event (censored), 1,858 days; disease-free interval: no event (censored), 1,858 days; progression-free interval: no event (censored), 1,858 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-OR-A5LM-01A-11D-A29H-01): tumor purity 0.76, ploidy 4.73, whole-genome doublings 2.
